Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAE3, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAE3-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: Hepatocellular carcinoma suggested

Specimen : Liver and Liver mass

Gross Photo :

ROSS:

Specimen status: Fresh

Operation: Partial hepatectomy

Cholecystectomy

Organs: Liver (19.0 x 13.0 x 8.5 cm, 741.5 gm)

Gallbladder (9.0 cm in length, 3.3 cm in diameter, and 0.5 cm in thickness)

Lesion:

<Liver>

A large dark red round tumor mass (16.5 x 12.0 cm)

Cut surface: Yellowish tan and solid with area of necrosis

Gross type:

HCC: Expanding nodular, multinodular confluent

Resection margin: Not involved grossly (safety margin: 0.5 cm)

Others:

Satellite nodule: No

Remaining parenchyma: Periportal-septal (stage 2-3)

<Gallbladder>

No stone

Representative sections submitted

Gross photo: Present

Blocks

TB, T1-6, tumor mass x 7

L,NB, liver parenchyma x 2

GB, gallbladder x 1

MICROSCOPIC:

Hepatocellular carcinoma: Yes

The worst differentiation II

The major differentiation II

Histologic type: Trabecular

Cell type: Hepatic

Fatty change: No

Fibrous capsule formation: No

Septum formation: No

Surgical resection margin invasion: No, safety margin (0.5 cm)

Serosal invasion: No

Portal vein invasion: No

Microvessel invasion: No

Intrahepatic metastasis: No

Multicentric occurrence: No

ICD O-3

Carcinoma, hepatocellular NOS
8170/3

Site: Liver C22.0

JA 5/20/14

[page 2 of 2]
NOT reported. Gross:

liver,ectomy,hepatocellular carcinoma
T56000, P10, M81703
gallbladder,ectomy,chronic cholecystitis
T57000, P10, M43005
lymph node,biopsy,no tumor
T08000, P50, M09450

DIAGNOSIS:

Liver, partial hepatectomy:

Hepatocellular carcinoma, well differentiated

Gallbladder, cholecystectomy:

Chronic cholecystitis

Lymph node, pericystic, biopsy:

No tumor present (0/1)

Suggestion :

Source: NCI Genomic Data Commons file ded72b34-9f78-4b3d-8a27-a396cf756b00 (TCGA-DD-AAE3.FED7CE87-1B13-4035-A76B-CEC1045B93C4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).